MMRF case MMRF_2568 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/9a460ce3-860b-4fcc-800e-f6b055413c23

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 69.9 years (25,526 days); ISS stage: I; Days to last known disease status: 684 days (1.9 years); Days to last follow up: 684 days (1.9 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 169 days; Days to treatment end: 169 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 171 days; Days to treatment end: 171 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 684.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -9 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 43.8 mg/dL; Immunoglobulin G 3.19 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 2.1 µg/mL; Lactate Dehydrogenase 3.55 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 16.5 ×10⁹/L; Absolute Neutrophil 14 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 5.34 mmol/L; C-Reactive Protein 0.7 mg/dL.
- Day 86 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.95 mg/dL; Immunoglobulin G 2.67 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 1.97 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.53 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 5.67 mmol/L.
- Day 172 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.43 mg/dL; Immunoglobulin G 2.63 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.45 mmol/L; Albumin 43 g/L; Total Protein 6.1 g/dL; Glucose 6.27 mmol/L.
- Day 253 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.84 mg/dL; Immunoglobulin G 3.16 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 3.88 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.58 mmol/L; Albumin 46 g/L; Total Protein 6.4 g/dL; Glucose 5.06 mmol/L.
- Day 359 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 3.98 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 1.5 µg/mL; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.5 mmol/L; Albumin 44 g/L; Total Protein 6.5 g/dL; Glucose 5.39 mmol/L.
- Day 450 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.48 mg/dL; Immunoglobulin G 5.97 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 2.1 µg/mL; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.5 mmol/L; Albumin 37 g/L; Total Protein 6.1 g/dL; Glucose 6.49 mmol/L.
- Day 527 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.87 mg/dL; Immunoglobulin G 6.86 g/L; Immunoglobulin A 0.5 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 85 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.5 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 5.78 mmol/L.
- Day 625 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.94 mg/dL; Immunoglobulin G 8.14 g/L; Immunoglobulin A 0.77 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 2.1 µg/mL; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 80 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.48 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 6.38 mmol/L.

Other clinical attributes
- Day -9: Weight: 70 kg; Height: 174 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2568_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -9 days.
- Sample MMRF_2568_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -9 days.
